Somatic mutation profile of tumor specimen TCGA-HC-8265-01A (aliquot TCGA-HC-8265-01A-11D-2260-08) from TCGA case TCGA-HC-8265, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.8 years (24,382 days).
Specimen TCGA-HC-8265-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bed47f5-9782-4f80-8f85-b3fea20809cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-8265-10A (Blood Derived Normal), aliquot TCGA-HC-8265-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a76cc74-d3ce-4b67-a163-0bf650143d3a

The open-access MAF lists 57 somatic variants for this specimen: 43 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 13, Frame Shift Del 5, Nonsense Mutation 4, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.659A>G p.N220S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV67129004; called by muse, mutect2
- ADGRF1 | c.367T>C p.Y123H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV64799686; called by muse, mutect2, varscan2
- AGXT | c.682A>C p.K228Q | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV56753375, COSV56753759; called by muse, mutect2, varscan2
- ARPC5L | c.390G>C p.W130C | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52346474; called by muse, mutect2, varscan2
- C1QL4 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs750966716, COSV57743425; called by muse, mutect2, varscan2
- CDK12 | c.1792C>T p.Q598* | Nonsense Mutation (SNP) | VAF 67/230 reads (29%) | catalogued as COSV70999749, COSV99067788; called by muse, mutect2, varscan2
- CHRAC1 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.102); catalogued as COSV55269774; called by muse, mutect2
- CT45A10 | c.300C>A p.S100R | Missense Mutation (SNP) | VAF 93/157 reads (59%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.986); catalogued as COSV65921142; called by muse, mutect2, varscan2
- CYSLTR2 | c.391G>C p.V131L | Missense Mutation (SNP) | VAF 56/235 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV56165402; called by muse, mutect2, varscan2
- DDI1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as rs138983347, COSV56380960; called by muse, mutect2, varscan2
- DDIT4 | c.536T>A p.L179Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56577203; called by muse, mutect2, varscan2
- DSP | c.2429G>A p.G810E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as rs1214751115, COSV65791838; called by muse, mutect2, varscan2
- FGD1 | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1159898849, COSV64308291, COSV64308548; called by muse, mutect2, varscan2
- FOXA1 | c.746A>T p.D249V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51644631, COSV51650069; called by muse, varscan2
- GABRG1 | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV54951311, COSV54956057; called by muse, mutect2
- IRAG1 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs371956442; called by muse, mutect2, varscan2
- KIF20A | c.1000G>T p.D334Y | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50145987; called by muse, mutect2, varscan2
- LANCL1 | c.195G>A p.W65* | Nonsense Mutation (SNP) | VAF 129/605 reads (21%) | catalogued as COSV52064486, COSV52066226; called by muse, mutect2, varscan2
- MDN1 | c.15638A>G p.K5213R | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV65518838, COSV65523427; called by muse, mutect2, varscan2
- MYH7 | c.3994G>A p.A1332T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs397516198, CM115870, COSV62515921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NDNF | c.885C>A p.N295K | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV65632880; called by muse, mutect2
- NEURL4 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100224042, COSV59757300; called by muse, mutect2, varscan2
- OBSCN | c.4541G>A p.C1514Y | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52752991; called by muse, mutect2, varscan2
- PCDH11X | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.078); catalogued as COSV53451571; called by muse, mutect2, varscan2
- PCDH15 | c.5059C>A p.P1687T (on ENST00000644397 / NM_001354429.2; = p.P1629T on NM_001142771.2) | Missense Mutation (SNP) | VAF 107/343 reads (31%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.162); catalogued as rs762646821, COSV64680965; called by muse, mutect2, varscan2
- POTEE | c.164A>C p.K55T | Missense Mutation (SNP) | VAF 16/388 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV58226705; called by muse, mutect2
- RMC1 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV52570977; called by muse, mutect2, varscan2
- SCAF8 | c.1304C>G p.S435* | Nonsense Mutation (SNP) | VAF 10/113 reads (9%) | catalogued as COSV65790750; called by muse, mutect2
- STAT1 | c.649A>C p.I217L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV61189714; called by muse, mutect2, varscan2
- TBC1D7 | c.227A>G p.K76R | Missense Mutation (SNP) | VAF 25/348 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs766400367, COSV58243540, COSV58243580; called by muse, mutect2
- TCEA1 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV67172230, COSV67173470; called by muse, mutect2, varscan2
- TMC1 | c.2212G>C p.A738P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV52769779; called by muse, mutect2
- TMEM176A | c.424T>C p.Y142H | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV50240413; called by muse, mutect2
- TNS1 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs767974267, COSV50693621; called by muse, mutect2
- TOP2B | c.3662del p.G1221Afs*5 (on ENST00000264331 / NM_001330700.2; = p.G1216Afs*5 on NM_001068.3) | Frame Shift Del (DEL) | VAF 29/133 reads (22%) | catalogued as COSV51977176; called by mutect2, pindel, varscan2
- TTN | c.98697T>A p.Y32899* (on ENST00000591111; = p.Y25475* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 35/170 reads (21%) | catalogued as COSV59941353; called by muse, mutect2, varscan2
- UGT1A7 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 35/702 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs371311391; called by muse, mutect2
- ZNF282 | c.1672C>T p.H558Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as rs780041275, COSV50479329; called by muse, mutect2, varscan2
- CDK12 | c.163_178del p.L55Qfs*32 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | called by mutect2, pindel, varscan2
- DMXL1 | c.6521dup p.S2175Vfs*28 | Frame Shift Ins (INS) | VAF 47/208 reads (23%) | called by mutect2, pindel, varscan2
- MAGEC3 | c.814del p.Q272Rfs*5 | Frame Shift Del (DEL) | VAF 78/159 reads (49%) | called by mutect2, pindel, varscan2
- SEMA6A | c.1534del p.G513Afs*24 | Frame Shift Del (DEL) | VAF 29/145 reads (20%) | called by mutect2, pindel, varscan2
- UTP15 | c.624_639del p.V209Ffs*22 | Frame Shift Del (DEL) | VAF 28/206 reads (14%) | called by mutect2, pindel
- DLG5 | c.4218G>A p.T1406= | Silent (SNP) | VAF 7/142 reads (5%) | catalogued as COSV64947233; called by muse, mutect2
- IFT52 | c.1077G>A p.T359= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as rs772210633, COSV65974632, COSV65975919; called by muse, mutect2, varscan2
- IL12A | c.327A>G p.T109= | Silent (SNP) | VAF 5/89 reads (6%) | catalogued as COSV59758894; called by muse, mutect2
- KIAA0513 | c.618G>A p.A206= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs753555506, COSV50740733; called by muse, mutect2, varscan2
- NLRP3 | c.1995C>G p.S665= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV60229527; called by muse, mutect2
- OPA1 | c.309C>T p.L103= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV62479482; called by muse, mutect2
- PCLO | c.11550G>A p.Q3850= | Silent (SNP) | VAF 15/342 reads (4%) | catalogued as COSV61622864; called by muse, mutect2
- POLR3D | c.399A>G p.G133= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs200322424, COSV60570742; called by muse, mutect2, varscan2
- PPARGC1A | c.1458C>T p.D486= | Silent (SNP) | VAF 35/148 reads (24%) | catalogued as COSV53525606, COSV53528274; called by muse, mutect2, varscan2
- SNX13 | c.1120C>T p.L374= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV68064207, COSV68065224; called by muse, mutect2, varscan2
- SYNE2 | c.10308C>G p.G3436= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV59943564; called by muse, mutect2
- TMC1 | c.2214T>G p.A738= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV52769796; called by muse, mutect2
- ZNF154 | c.657T>C p.C219= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as COSV70744839; called by muse, mutect2, varscan2
- TTN | c.34264+4792G>T | Intron (SNP) | VAF 18/160 reads (11%) | catalogued as COSV59941392; called by muse, mutect2, varscan2
